Gene-level copy-number profile of tumor specimen TCGA-DU-6395-01A from TCGA case TCGA-DU-6395, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 31.7 years (11,584 days).
Specimen TCGA-DU-6395-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.e67478af-40c1-4d97-b054-57eddd8e2f5c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-6395-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/73fd8f4e-0319-4773-ae85-0a39d01f2756

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,464; copy number 2: 52,122; copy number 3: 320; copy number 4: 3,735; copy number 5: 179.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-6395-01A-12D-1704-01): tumor purity 0.88, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 179 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:35,561,831–37,034,268, 61 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr12:2,440,189–5,092,742, 79 genes, copy number 5 (broad region; genes not listed).
- chr12:9,448,295–10,338,292, 39 genes, copy number 5 (within-gene range 4–5): AC092821.3, AC092821.1, AC092821.2, KLRB1, RNU6-700P, GOT2P3, AC010186.4, AC010186.1, AC010186.2, AC010186.3, CLEC2D, NPM1P7, LINC02390, CLECL1, CD69, GCNAP1, KLRF1, CLEC2B, AC091814.1, KLRF2, CLEC2A, LINC02470, CLEC12A-AS1, CLEC12A, CLEC1B, CLEC12B, AC024224.2, CLEC9A, AC024224.1, CLEC1A, RN7SKP161, HNRNPABP1, CLEC7A, OLR1, TMEM52B, GABARAPL1, GABARAPL1-AS1, KLRD1, LINC02617.

Autosomal genes at a single copy (total copy number 1): 1,077. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
